Somatic mutation profile of tumor specimen MMRF_1293_1_BM_CD138pos (aliquot MMRF_1293_1_BM_CD138pos_T1_KAS5U_L01708) from MMRF case MMRF_1293, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.4 years (21,678 days).
Specimen MMRF_1293_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f8f21e2-e329-49c3-930d-415110756100.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1293_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1293_2_PB_WBC_C1_KBS5U_L05569; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f298b92-f7db-49fc-9614-d54cc9fb3d91

The open-access MAF lists 87 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 26, Intron 11, Silent 9, Nonsense Mutation 4, Splice Region 2, RNA 1, 5'Flank 1, 3'Flank 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 83/159 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.485); catalogued as rs775569138, COSV50987018; called by muse, mutect2, varscan2
- ACTL9 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs782533493, COSV61005098, COSV61006897; called by muse, mutect2, varscan2
- ANK2 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764760708, COSV52170121, COSV52188897; called by muse, mutect2, varscan2
- ATG9B | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1193140397; called by muse, mutect2, varscan2
- BICD1 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs183425481, COSV55675098; called by muse, mutect2, varscan2
- CCDC18 | c.3839G>C p.R1280T (on ENST00000343253 / NM_001306076.1; = p.R1281T on NM_206886.4) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs757562852; called by muse, mutect2, varscan2
- CDKL5 | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 114/118 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs1413837885; called by muse, mutect2, varscan2
- H1-4 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56799905, COSV56803909; called by muse, mutect2, varscan2
- HTR2C | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 73/73 reads (100%) | catalogued as COSV52221996; called by muse, mutect2, varscan2
- IGHJ4 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 79/81 reads (98%) | PolyPhen benign (0.014); catalogued as rs555110696; called by muse, mutect2, varscan2
- IGHV2-70D | c.316A>C p.M106L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.073); catalogued as rs1310513170; called by muse, varscan2
- IRX4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs754848816, COSV51474073; called by muse, mutect2, varscan2
- PGAP2 | c.419-3C>T | Splice Region (SNP) | VAF 152/507 reads (30%) | catalogued as rs202073184; called by muse, mutect2, varscan2
- SOGA3 | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs369861960; called by muse, mutect2, varscan2
- TGM4 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs202075944; called by muse, mutect2, varscan2
- ZCCHC3 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs779001468; called by muse, varscan2
- ATP13A5 | c.151T>C p.F51L | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CACNA1S | c.4201G>T p.E1401* | Nonsense Mutation (SNP) | VAF 51/127 reads (40%) | called by muse, mutect2, varscan2
- CHIA | c.927C>A p.F309L (on ENST00000343320; = p.F201L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CLPTM1L | c.172T>G p.Y58D | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DGKB | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ERC2 | c.447T>G p.D149E | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDE | c.1153+7A>C | Splice Region (SNP) | VAF 114/220 reads (52%) | called by muse, varscan2
- IGHV2-70 | c.118_135del p.T40_G45del | In Frame Del (DEL) | VAF 40/46 reads (87%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, varscan2
- IGHV2-70D | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- MAGI1 | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- MED14 | c.1315G>C p.V439L | Missense Mutation (SNP) | VAF 49/53 reads (92%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- METAP2 | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2
- MUC3A | c.8008A>G p.T2670A | Missense Mutation (SNP) | VAF 200/1398 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PARD3 | c.3628G>T p.E1210* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- PCNX1 | c.4787T>G p.L1596* | Nonsense Mutation (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- PHLPP2 | c.213dup p.P72Tfs*30 | Frame Shift Ins (INS) | VAF 4/54 reads (7%) | called by mutect2, pindel
- SLC12A1 | c.1106A>C p.N369T | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCAL1 | c.1556T>G p.L519R | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SPINK5 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ZAN | c.1733G>C p.S578T | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ZNF169 | c.1802A>G p.E601G | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH4 | c.549C>T p.R183= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1228050535; called by mutect2, varscan2
- DOCK2 | c.4335C>G p.S1445= | Silent (SNP) | VAF 42/152 reads (28%) | called by muse, mutect2, varscan2
- ETFB | c.699C>T p.R233= | Silent (SNP) | VAF 28/158 reads (18%) | called by muse, mutect2, varscan2
- IGHD2-2 | c.22C>T p.L8= | Silent (SNP) | VAF 29/30 reads (97%) | catalogued as rs781865993; called by muse, mutect2, varscan2
- IGKC | c.150T>G p.G50= | Silent (SNP) | VAF 40/40 reads (100%) | called by muse, varscan2
- KCNC1 | c.249C>T p.C83= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV56391450; called by muse, mutect2, varscan2
- KRT5 | c.507C>T p.R169= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs200658792, COSV52859976; called by muse, mutect2, varscan2
- PRDM10 | c.2892T>C p.D964= | Silent (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- TRIB3 | c.306G>A p.Q102= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- ABL2 | c.*5243T>A | 3'UTR (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- AGBL3 | c.2343-5715T>G | Intron (SNP) | VAF 92/143 reads (64%) | catalogued as rs537988721; called by muse, mutect2
- AGBL5 | c.*348T>G | 3'UTR (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2, varscan2
- BMP6 | c.*1184_*1186del | 3'UTR (DEL) | VAF 84/154 reads (55%) | called by pindel, varscan2
- BRWD1 | c.6571+3215T>C | Intron (SNP) | VAF 70/144 reads (49%) | called by muse, mutect2, varscan2
- C11orf71 | c.343+158T>G | Intron (SNP) | VAF 22/29 reads (76%) | called by muse, mutect2
- C11orf71 | c.343+61T>C | Intron (SNP) | VAF 102/149 reads (68%) | called by muse, mutect2, varscan2
- C6orf141 | c.*148+371T>C | Intron (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- CACNA1B | c.*1510G>T | 3'UTR (SNP) | VAF 45/163 reads (28%) | called by muse, mutect2, varscan2
- CADM2 | c.*23T>C | 3'UTR (SNP) | VAF 290/444 reads (65%) | catalogued as rs1388231729; called by muse, mutect2, varscan2
- CAMKMT | c.376+66629G>A | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- DUSP6 | chr12:89353214 ins T | 5'Flank (INS) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- ELAPOR1 | c.2973+427G>A | Intron (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- EPCAM | c.76+85T>C | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- GLO1 | c.*885A>G | 3'UTR (SNP) | VAF 48/152 reads (32%) | catalogued as rs1329038617; called by muse, mutect2, varscan2
- HIBCH | c.*105A>G | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- HLA-A | c.*148del | 3'UTR (DEL) | VAF 104/360 reads (29%) | called by pindel, varscan2
- HPS5 | c.3329+11T>C | Intron (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- IL17D | c.*279A>G | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- INSC | c.*761T>C | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- JDP2 | chr14:75473155 C>T | 3'Flank (SNP) | VAF 3/23 reads (13%) | catalogued as rs1309931917; called by muse, mutect2
- KLF13 | c.*3046A>G | 3'UTR (SNP) | VAF 50/133 reads (38%) | called by muse, mutect2, varscan2
- KLF3 | c.*2020G>A | 3'UTR (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- LINC01119 | n.1456_1458del | RNA (DEL) | VAF 9/34 reads (26%) | catalogued as rs757384658; called by pindel, varscan2*
- MCCD1 | c.*30G>A | 3'UTR (SNP) | VAF 3/44 reads (7%) | catalogued as rs1253384988; called by muse, mutect2
- NDUFAF1 | c.759+611C>T | Intron (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*6937del | 3'UTR (DEL) | VAF 36/128 reads (28%) | catalogued as rs200299501; called by mutect2, varscan2
- RNF115 | c.*420A>G | 3'UTR (SNP) | VAF 59/119 reads (50%) | catalogued as rs1197904396; called by muse, mutect2, varscan2
- SEMA3E | c.*3279C>A | 3'UTR (SNP) | VAF 69/174 reads (40%) | called by muse, mutect2, varscan2
- SRRM4 | c.*1733C>T | 3'UTR (SNP) | VAF 86/169 reads (51%) | catalogued as rs1419700230; called by muse, mutect2, varscan2
- STC2 | c.506+76G>A | Intron (SNP) | VAF 21/77 reads (27%) | catalogued as rs767834711; called by muse, mutect2, varscan2
- SYNPO2L | c.*284C>T | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- SYT10 | c.*1203A>G | 3'UTR (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- TMEM33 | c.*1593A>G | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- TTC9 | c.*3338G>A | 3'UTR (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- VGLL3 | c.*8114dup | 3'UTR (INS) | VAF 59/210 reads (28%) | called by mutect2, pindel, varscan2
- ZNF141 | c.*9378A>T | 3'UTR (SNP) | VAF 106/212 reads (50%) | called by muse, varscan2
- ZNF141 | c.*9426A>G | 3'UTR (SNP) | VAF 122/236 reads (52%) | called by muse, varscan2
- ZNF24 | c.*4478T>G | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- ZNF512B | c.*1764C>T | 3'UTR (SNP) | VAF 6/149 reads (4%) | called by muse, mutect2
